Somatic mutation profile of tumor specimen TCGA-22-1000-01A (aliquot TCGA-22-1000-01A-01W-0782-08) from TCGA case TCGA-22-1000, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.4 years (27,901 days).
Specimen TCGA-22-1000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2857bfc3-4888-424a-a026-71d34e75f917.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1000-11A (Solid Tissue Normal), aliquot TCGA-22-1000-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aabf0f70-96e4-4663-8bc3-87fb3a449c88

The open-access MAF lists 107 somatic variants for this specimen: 80 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 24, Frame Shift Ins 8, Nonsense Mutation 4, Splice Site 3, Intron 3, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 4/19 reads (21%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 24/206 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- XYLT2 | c.692dup p.V232Gfs*54 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | catalogued as rs797044806; ClinVar: pathogenic; called by pindel, varscan2
- ACSS3 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54092868; called by muse, mutect2, varscan2
- ADAM10 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53052740; called by muse, mutect2, varscan2
- ADAT1 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100329298; called by muse, mutect2
- ADGRV1 | c.12148G>A p.D4050N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs576743510, COSV67994519; ClinVar: likely benign; called by muse, mutect2, varscan2
- AICDA | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.67); catalogued as COSV99984347; called by muse, mutect2
- AMY2B | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 47/905 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1557770305; called by muse, mutect2
- C3AR1 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.361); catalogued as COSV99368914; called by muse, mutect2
- CARD14 | c.846G>A p.A282= | Splice Region (SNP) | VAF 8/69 reads (12%) | catalogued as rs1007674397; called by muse, mutect2
- CASC3 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 85/1311 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99230002; called by muse, mutect2
- CASC3 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 86/1318 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV99230003; called by muse, mutect2
- CDKN2A | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as CM014694, COSV58728864; called by muse, mutect2, varscan2
- CEP192 | c.6850A>G p.T2284A | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100381982; called by muse, mutect2
- CLEC4C | c.611C>A p.S204* | Nonsense Mutation (SNP) | VAF 10/238 reads (4%) | catalogued as COSV100665497; called by muse, mutect2
- COL12A1 | c.4468A>G p.M1490V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1230537277, COSV100486406; called by muse, mutect2, varscan2
- COPS4 | c.254A>T p.Y85F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as COSV100018818, COSV52313620; called by muse, mutect2, varscan2
- DIS3L | c.1597G>C p.D533H (on ENST00000319212 / NM_001143688.3; = p.D450H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100055551; called by muse, mutect2
- DMKN | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100302984; called by muse, mutect2, varscan2
- FOXN2 | c.537+1G>T p.X179_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100489464, COSV61318715; called by muse, mutect2
- HRH2 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99199901; called by muse, mutect2
- IQCJ | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs747662973, COSV101188772; called by muse, mutect2
- KIF17 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929656; called by muse, mutect2
- KIF2B | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1305227589, COSV52127518, COSV52133387; called by muse, mutect2
- KRT71 | c.279C>G p.C93W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1325592038, COSV99922381; called by muse, mutect2, varscan2
- LCP1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100550059; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 21/92 reads (23%) | catalogued as rs746133895; called by mutect2, varscan2
- LUZP2 | c.911C>G p.T304S | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV100421196; called by muse, mutect2, varscan2
- LYSMD3 | c.576A>C p.Q192H | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100270535; called by muse, mutect2, varscan2
- MAP3K1 | c.1423+1G>C p.X475_splice | Splice Site (SNP) | VAF 17/225 reads (8%) | catalogued as COSV101266817, COSV101267100; called by muse, mutect2
- MAP3K19 | c.254C>G p.T85S | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100209182; called by muse, varscan2
- MME | c.1498-2A>T p.X500_splice | Splice Site (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100852521; called by muse, mutect2
- MORC1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99227618, COSV99227663; called by muse, mutect2
- NCKAP5L | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100259171; called by muse, mutect2, varscan2
- OR2L3 | c.29A>T p.D10V | Missense Mutation (SNP) | VAF 59/549 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100742041; called by muse, mutect2, varscan2
- OR2M2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62899069, COSV62899483; called by muse, mutect2, varscan2
- OR3A1 | c.133A>T p.N45Y | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60163513; called by muse, mutect2
- OR4A15 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV59034598, COSV59035155; called by muse, mutect2
- PDE6H | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs868831954, COSV56760417, COSV99844047; called by muse, mutect2, varscan2
- PGR | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772031832, COSV99679028; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 23/177 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- PLXNA4 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 20/255 reads (8%) | catalogued as COSV58118382; called by muse, mutect2
- PROK1 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99602650; called by muse, mutect2, varscan2
- RAB3GAP2 | c.4093A>G p.I1365V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100228585; called by muse, mutect2
- RB1 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 59/439 reads (13%) | catalogued as COSV57301410, COSV57303024; called by muse, mutect2, varscan2
- RXFP2 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100034590; called by muse, mutect2, varscan2
- SELP | c.1596T>G p.Y532* | Nonsense Mutation (SNP) | VAF 28/390 reads (7%) | catalogued as COSV99740991; called by muse, mutect2
- SIPA1L1 | c.315C>G p.C105W | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV100665516; called by muse, mutect2
- SMO | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as rs1366851376, COSV99977057; called by muse, mutect2
- SPATA31E1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.794); catalogued as COSV100351001; called by muse, mutect2, varscan2
- SSR3 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99411220; called by muse, mutect2
- TGM4 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 44/501 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99942599; called by muse, mutect2
- TMCC1 | c.933G>C p.Q311H | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100261262; called by muse, mutect2
- TTN | c.9865C>A p.H3289N (on ENST00000591111; = p.H3243N on NM_003319.4) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | PolyPhen benign (0.415); catalogued as COSV100627604, COSV59863902; called by muse, mutect2, varscan2
- TUBGCP2 | c.1059dup p.S354Vfs*53 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs1034028742; called by pindel, varscan2
- ZXDA | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs45580541, COSV100699464; called by mutect2, varscan2
- ASPM | c.8461dup p.I2821Nfs*7 | Frame Shift Ins (INS) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- ATP7A | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CFAP36 | c.849del p.M284Cfs*3 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- CFP | c.967dup p.E323Gfs*34 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- CLSTN2 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND1A | c.240C>G p.S80R | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC1H1 | c.10313G>T p.R3438L | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.087); called by muse, mutect2
- EPB41L1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLT1 | c.87A>T p.L29F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by mutect2, varscan2
- IGKV1D-33 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KCNK18 | c.672C>A p.S224R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2
- LEMD3 | c.887dup p.L297Afs*4 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by pindel, varscan2
- METTL3 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPH | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR4A16 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 64/492 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.167); called by muse, varscan2
- PROS1 | c.1590C>A p.N530K | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SDAD1 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- SEC14L1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC38A4 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM43 | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.201); called by muse, mutect2
- TRPC5 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- WDR44 | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WDR76 | c.1214_1222del p.S405_S408delinsT | In Frame Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.3891C>G p.V1297= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs367545953, COSV53237745; called by muse, varscan2
- AP1S2 | c.90C>T p.I30= | Silent (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- ASB5 | c.561G>T p.L187= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as COSV99642052; called by muse, mutect2
- BDKRB2 | c.120G>A p.G40= | Silent (SNP) | VAF 45/290 reads (16%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1188C>T p.S396= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs773396302, COSV100347059, COSV57924678; called by muse, mutect2, varscan2
- CCDC91 | c.153G>T p.L51= | Silent (SNP) | VAF 96/965 reads (10%) | catalogued as rs141221873; called by muse, mutect2
- CHRNB2 | c.126C>T p.Y42= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV100872668; called by muse, mutect2
- GRIA4 | c.318G>A p.L106= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as rs1024262623, COSV56911324, COSV99234165; called by muse, mutect2
- GRM3 | c.780C>A p.I260= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV100862840, COSV64476925; called by muse, mutect2
- GSPT2 | c.1623G>T p.A541= | Silent (SNP) | VAF 21/205 reads (10%) | catalogued as rs1557348993; called by muse, mutect2, varscan2
- IL3RA | c.1032C>G p.P344= | Silent (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- IPO13 | c.2676G>A p.L892= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV99664712; called by muse, mutect2, varscan2
- KATNB1 | c.486G>A p.L162= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- MYO1H | c.1440T>C p.A480= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- NAT2 | c.738T>C p.Y246= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99674187; called by muse, mutect2, varscan2
- OR5C1 | c.850C>T p.L284= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as COSV101030604; called by muse, mutect2, varscan2
- PCDHA3 | c.144C>T p.I48= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs782016888, COSV65365985, COSV65369479, COSV65370196; called by muse, varscan2
- PIP4P1 | c.567C>A p.R189= | Silent (SNP) | VAF 78/2682 reads (3%) | called by muse, mutect2
- PLEKHA7 | c.2592A>T p.P864= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100262001; called by muse, mutect2, varscan2
- SLC36A4 | c.276A>G p.G92= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100419456; called by muse, mutect2
- TLDC2 | c.268C>T p.L90= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV99456171; called by muse, mutect2, varscan2
- TRIML2 | c.1173C>T p.L391= | Silent (SNP) | VAF 67/245 reads (27%) | catalogued as COSV100456316; called by muse, mutect2
- TSPEAR | c.267C>T p.I89= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as rs782010486, COSV59962692; called by muse, mutect2
- ZNF792 | c.786C>G p.A262= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV101289755; called by muse, mutect2
- CIT | c.2082+1953C>T | Intron (SNP) | VAF 52/215 reads (24%) | catalogued as COSV99950798; called by muse, mutect2, varscan2
- PRUNE2 | c.756+35146G>A | Intron (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- RPL23A | c.387-81T>C | Intron (SNP) | VAF 8/46 reads (17%) | called by mutect2, varscan2
